Somatic mutation profile of tumor specimen TCGA-ZG-A9M4-01A (aliquot TCGA-ZG-A9M4-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9M4, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.8 years (24,030 days).
Specimen TCGA-ZG-A9M4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b39b6891-18fa-4908-ab20-2ab6168fd07b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9M4-10A (Blood Derived Normal), aliquot TCGA-ZG-A9M4-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02ddc6fa-2ef9-4017-bcbf-447e9889144e

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 21, Silent 10, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD53 | c.267C>G p.D89E | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV99721470; called by muse, mutect2, varscan2
- ARID1B | c.2482G>A p.G828S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); catalogued as rs150249745; called by muse, mutect2, varscan2
- CCDC88A | c.5280A>C p.K1760N (on ENST00000436346 / NM_001365480.1; = p.K1732N on NM_018084.5) | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.287); catalogued as COSV99710770; called by muse, mutect2, varscan2
- DOCK8 | c.5936G>A p.G1979D | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101209995; called by muse, mutect2, varscan2
- EEF2KMT | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs762583437, COSV52156697; called by muse, mutect2, varscan2
- FBXL6 | c.1463G>T p.S488I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV100095892; called by muse, mutect2, varscan2
- FLNC | c.6683G>A p.R2228Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.392); catalogued as rs765438770, COSV100368546, COSV57958306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPAT3 | c.1018G>T p.A340S | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV100023125; called by muse, mutect2, varscan2
- KCNK2 | c.985G>A p.A329T (on ENST00000444842 / NM_001017425.3; = p.A314T on NM_014217.4) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs897321993, COSV101221867; called by muse, mutect2, varscan2
- KDM6A | c.3763C>T p.R1255W | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1450363794, COSV65037148; ClinVar: uncertain significance; called by muse, mutect2
- LTN1 | c.58C>G p.R20G | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63734966; called by muse, mutect2, varscan2
- LZTS1 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs371854944, COSV56115699; called by muse, mutect2, varscan2
- MDN1 | c.1359G>C p.W453C | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101021552; called by muse, mutect2, varscan2
- OR2J2 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs775420912, COSV65848084; called by muse, mutect2, varscan2
- PAEP | c.181A>C p.I61L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV99478959; called by muse, mutect2, varscan2
- PARP8 | c.649A>G p.T217A | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs369907021; called by muse, mutect2, varscan2
- PPL | c.146_147del p.E49Gfs*6 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | catalogued as rs1217908229; called by pindel, varscan2
- PTPN23 | c.4398C>G p.C1466W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV99650780; called by muse, mutect2, varscan2
- RIN3 | c.2312A>T p.D771V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99379577; called by muse, varscan2
- RNF144A | c.134T>G p.L45R | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.526); catalogued as COSV100305851; called by muse, mutect2, varscan2
- SCN7A | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV69269672; called by muse, mutect2, varscan2
- TET3 | c.5185C>T p.R1729W | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs995896822, COSV101327970; called by muse, mutect2, varscan2
- TFDP1 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as COSV100945954; called by muse, mutect2, varscan2
- ZBTB9 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as rs756259555, COSV67702263; called by muse, mutect2, varscan2
- COL4A3 | c.277_279+7del p.X93_splice | Splice Site (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- TP53 | c.429_435del p.Q144Gfs*24 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- BPIFB4 | c.324C>A p.I108= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV100971583; called by muse, mutect2, varscan2
- CDC45 | c.1314C>T p.L438= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs1026286716, COSV99596848; called by muse, mutect2
- CLEC17A | c.750C>T p.R250= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV100355453; called by muse, mutect2, varscan2
- JPH2 | c.261A>G p.T87= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100652601; called by muse, mutect2, varscan2
- NDN | c.306G>A p.A102= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as rs757964674, COSV100086557; called by muse, mutect2, varscan2
- NIN | c.2838G>A p.R946= | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as COSV99814201; called by muse, mutect2, varscan2
- RAB33A | c.354C>T p.D118= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs892513764, COSV57061869; called by muse, mutect2, varscan2
- RALBP1 | c.1161G>A p.T387= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs150447479; called by muse, mutect2, varscan2
- RPL3L | c.807C>T p.A269= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as rs148725709; called by muse, mutect2, varscan2
- ZC2HC1A | c.234T>C p.S78= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99804236; called by muse, mutect2, varscan2
